TCGA case TCGA-GN-A267 — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Lymph nodes; Tissue source site: Roswell. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ab74d6ed-880e-4470-bfd5-2974a4c3a0d7

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 38 years; Vital status: Dead; Days to death: 1,960 days (5.4 years).

Diagnoses (11)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C77.3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Lymph nodes of axilla or arm; Classification of tumor: Progression; Age at diagnosis: 42.5 years (15,521 days); Days to diagnosis: 1,466 days (4.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Interferon; Timepoint category: Prior to Procurement.
   Recorded as not given: Radiation Therapy, NOS, prior to procurement.
2. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Age at diagnosis: 38.5 years (14,055 days); Year of diagnosis: 2005; AJCC staging edition: 6th; AJCC pathologic T: T4a; AJCC pathologic N: N1a; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Melanoma known primary: Yes.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 1,520 days (4.2 years); Days to treatment end: 1,530 days (4.2 years).
   Recorded as not given: adjuvant Radiation Therapy, NOS.
3. Malignant melanoma, NOS: Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Clark level: IV; Sites of involvement: Skin, Trunk; Ulceration indicator: No.
   Pathology details: Breslow thickness category: >4.0 mm.
   Recorded as not given: Radiation Therapy, NOS.
4. Recurrence of diagnosis 2 (Malignant melanoma, NOS). Age at diagnosis: 39.7 years (14,511 days); Days to diagnosis: 456 days (1.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 505 days (1.4 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.
5. Recurrence of diagnosis 2 (Malignant melanoma, NOS). Age at diagnosis: 40.7 years (14,861 days); Days to diagnosis: 806 days (2.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 814 days (2.2 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.
6. Recurrence of diagnosis 2 (Malignant melanoma, NOS). Age at diagnosis: 40.9 years (14,951 days); Days to diagnosis: 896 days (2.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 937 days (2.6 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.
7. Recurrence of diagnosis 2 (Malignant melanoma, NOS). Age at diagnosis: 42.4 years (15,470 days); Days to diagnosis: 1,415 days (3.9 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 1,437 days (3.9 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.
8. Metastasis of diagnosis 2 (Malignant melanoma, NOS), site: Bone, NOS. Age at diagnosis: 42.7 years (15,610 days); Days to diagnosis: 1,555 days (4.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 1,577 days (4.3 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.
9. Metastasis of diagnosis 2 (Malignant melanoma, NOS), site: Lung, NOS. Age at diagnosis: 42.9 years (15,686 days); Days to diagnosis: 1,631 days (4.5 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
10. Metastasis of diagnosis 2 (Malignant melanoma, NOS), site: Liver. Age at diagnosis: 42.9 years (15,686 days); Days to diagnosis: 1,631 days (4.5 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
11. Metastasis of diagnosis 2 (Malignant melanoma, NOS), site: Brain, NOS. Age at diagnosis: 43.2 years (15,784 days); Days to diagnosis: 1,729 days (4.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.

Follow-up (9 entries)
- Day 456 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 456 days (1.2 years).
- Day 806 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 806 days (2.2 years).
- Day 896 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 896 days (2.5 years).
- Day 1,415 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 1,415 days (3.9 years).
- Day 1,555 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 1,555 days (4.3 years).
- Day 1,631 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 1,631 days (4.5 years).
- Day 1,631 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 1,631 days (4.5 years).
- Day 1,729 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Brain, NOS; Days to progression: 1,729 days (4.7 years).
- Days to follow up: 1,960 days (5.4 years); Disease response: With Tumor.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 8.6.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 96 kg; Height: 167 cm; BMI: 34.4.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-GN-A267-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-GN-A267-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT; Initial weight: 110 mg.
  Slide TCGA-GN-A267-06A-02-TSB: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.
- Sample TCGA-GN-A267-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Breslow thickness at diagnosis: 5.2; Primary melanoma tumor ulceration: No; Radiation therapy to primary: No; Primary location: Regional Lymph Node; Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: Yes; Ifn treatment 90 days prior to resection: Yes.
- Sites of primary melanomas: Primary multiple at diagnosis: No; Primary at diagnosis count: 1.
- Sites of primary melanomas, Site: Submitted tumor site: Trunk; Melanoma primary count: 1.
- Drug treatment: Regimen number: 1; Pharmaceutical therapy drug name: Temodar.

GDC annotations on this case (curator notes; quoted as recorded):
- Acceptable treatment for TCGA tumor: Patient received interferon for the specimen submitted to TCGA.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,960 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,960 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 456 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-GN-A267-06A-21D-A194-01): tumor purity 0.74, ploidy 2.02, whole-genome doublings 0.
